Somatic mutation profile of tumor specimen HCM-CSHL-0807-C54-01A (aliquot HCM-CSHL-0807-C54-01A-11D-A85K-36) from HCMI case HCM-CSHL-0807-C54, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: female; Vital status: Alive; Primary diagnosis: Carcinoma, undifferentiated, NOS; Tissue or organ of origin: Uterus, NOS; AJCC pathologic stage: Stage IA; FIGO stage: Stage IA; Tumor grade: G3.
Specimen HCM-CSHL-0807-C54-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f96df2de-caa6-42fc-9af9-6134e2447fb5.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-CSHL-0807-C54-11A (Solid Tissue Normal), aliquot HCM-CSHL-0807-C54-11A-01D-A85K-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/3f95c18f-ff05-4a6e-aefd-4466793ebdcd

The open-access MAF lists 451 somatic variants for this specimen: 308 protein-altering or splice-affecting, 123 silent, 20 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 227, Silent 123, Frame Shift Del 48, Frame Shift Ins 12, Nonsense Mutation 11, Intron 11, In Frame Del 4, 5'UTR 4, Splice Region 3, 3'Flank 3, Splice Site 2, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ARID1A | c.5161C>T p.R1721* | Nonsense Mutation (SNP) | VAF 99/230 reads (43%) | hotspot (GDC flag); catalogued as COSV61371260; called by muse, varscan2
- KANSL1 | c.2935_2936del p.L979Vfs*10 (on ENST00000574590 / NM_001193465.2; = p.L980Vfs*10 on NM_015443.4) | Frame Shift Del (DEL) | VAF 213/603 reads (35%) | catalogued as rs1568366050; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- PTEN | c.376G>A p.A126T | Missense Mutation (SNP) | VAF 121/280 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1554898129, CM110132, COSV64288974, COSV64292774, COSV64296979; ClinVar: likely pathogenic / uncertain significance; called by muse, varscan2
- PTPRT | c.1090C>T p.R364* | Nonsense Mutation (SNP) | VAF 149/332 reads (45%) | hotspot (GDC flag); catalogued as COSV61965733, COSV62024591; called by muse, mutect2, varscan2
- SCN2A | c.2810G>A p.R937H | Missense Mutation (SNP) | VAF 120/338 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1553579488, COSV51846923; ClinVar: pathogenic; called by muse, varscan2
- ABCD3 | c.161del p.K54Rfs*18 | Frame Shift Del (DEL) | VAF 110/247 reads (45%) | catalogued as COSV59867013; called by mutect2, varscan2
- AC008676.3 | c.627G>T p.Q209H | Missense Mutation (SNP) | VAF 131/353 reads (37%) | SIFT tolerated (0.54); PolyPhen benign (0); catalogued as COSV56637457, COSV56638075; called by muse, mutect2, varscan2
- ADAMTS14 | c.2945C>T p.A982V | Missense Mutation (SNP) | VAF 94/198 reads (47%) | SIFT tolerated (1); PolyPhen benign (0.009); catalogued as rs1438720264; called by muse, mutect2, varscan2
- AHCTF1 | c.2792del p.L931Cfs*8 (on ENST00000366508; = p.L905Cfs*8 on NM_015446.5) | Frame Shift Del (DEL) | VAF 118/525 reads (22%) | catalogued as rs1558240077, COSV58245421; called by mutect2, pindel, varscan2
- ANAPC2 | c.1490G>A p.R497H | Missense Mutation (SNP) | VAF 120/277 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs749339424, COSV60568920; called by muse, mutect2, varscan2
- ANAPC5 | c.2109G>T p.K703N | Missense Mutation (SNP) | VAF 38/294 reads (13%) | SIFT tolerated (0.15); PolyPhen benign (0.022); catalogued as rs373195408; called by muse, mutect2, varscan2
- ANKRD35 | c.896G>A p.R299K | Missense Mutation (SNP) | VAF 122/591 reads (21%) | SIFT tolerated (0.31); PolyPhen benign (0.005); catalogued as COSV62909879; called by muse, mutect2, varscan2
- ARHGAP17 | c.1441C>T p.R481W | Missense Mutation (SNP) | VAF 97/241 reads (40%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as rs199829132, COSV99253057; called by muse, mutect2, varscan2
- ASIC2 | c.829C>T p.Q277* | Nonsense Mutation (SNP) | VAF 102/226 reads (45%) | catalogued as COSV56757023; called by muse, mutect2, varscan2
- ATP2B3 | c.2086C>T p.R696C | Missense Mutation (SNP) | VAF 34/552 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as rs782683285; called by muse, mutect2
- ATPAF2 | c.239C>T p.T80I | Missense Mutation (SNP) | VAF 15/392 reads (4%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.852); catalogued as rs1210953910; called by muse, mutect2
- ATRNL1 | c.2087G>A p.S696N | Missense Mutation (SNP) | VAF 96/227 reads (42%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.777); catalogued as COSV61817977; called by muse, mutect2, varscan2
- BEST1 | c.682G>A p.D228N | Missense Mutation (SNP) | VAF 118/311 reads (38%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as rs267606676, CM097859, CM155011, COSV57121542; ClinVar: pathogenic / conflicting interpretations of pathogenicity; called by muse, mutect2, varscan2
- BRF2 | c.892G>A p.G298S | Missense Mutation (SNP) | VAF 153/360 reads (43%) | SIFT tolerated (0.08); PolyPhen benign (0.003); catalogued as rs983775121, COSV55103603; called by muse, mutect2, varscan2
- BTBD18 | c.1168G>A p.G390R | Missense Mutation (SNP) | VAF 118/266 reads (44%) | SIFT tolerated (0.35); PolyPhen benign (0.001); catalogued as rs1433272019; called by muse, mutect2, varscan2
- CACNA1A | c.4888C>T p.R1630C | Missense Mutation (SNP) | VAF 35/279 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as rs747020168, COSV100802605, COSV64199885; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CACNA1B | c.108del p.L37Cfs*64 | Frame Shift Del (DEL) | VAF 103/788 reads (13%) | catalogued as rs1474416938; called by mutect2, pindel, varscan2
- CARD11 | c.1834G>A p.G612R | Missense Mutation (SNP) | VAF 155/315 reads (49%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.873); catalogued as rs755710637, COSV62757067; called by muse, mutect2, varscan2
- CBL | c.557C>T p.A186V | Missense Mutation (SNP) | VAF 101/241 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV50662923; called by muse, mutect2, varscan2
- CDC42BPG | c.4208G>A p.R1403H | Missense Mutation (SNP) | VAF 149/356 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.959); catalogued as rs1424452327, COSV61349164; called by muse, mutect2, varscan2
- CDH16 | c.1686del p.K563Sfs*22 | Frame Shift Del (DEL) | VAF 40/440 reads (9%) | catalogued as rs776664434; called by mutect2, pindel
- CFHR5 | c.1117G>T p.G373W | Missense Mutation (SNP) | VAF 104/498 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56827976; called by muse, mutect2, varscan2
- CHST8 | c.104C>T p.T35M | Missense Mutation (SNP) | VAF 141/343 reads (41%) | SIFT tolerated (0.11); PolyPhen benign (0.154); catalogued as rs538795960, COSV52859119; called by muse, mutect2, varscan2
- CIITA | c.3254C>T p.T1085M | Missense Mutation (SNP) | VAF 134/400 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs752458730; called by muse, mutect2, varscan2
- CLDN22 | c.145G>A p.G49R | Missense Mutation (SNP) | VAF 101/329 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); catalogued as COSV60109730; called by muse, varscan2
- CNTLN | c.3922del p.M1308* | Frame Shift Del (DEL) | VAF 28/321 reads (9%) | catalogued as rs761011518, COSV99078405; called by mutect2, pindel
- CNTN3 | c.649C>T p.R217C | Missense Mutation (SNP) | VAF 77/178 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs766479438; called by muse, varscan2
- COMMD2 | c.28A>G p.K10E | Missense Mutation (SNP) | VAF 154/358 reads (43%) | SIFT deleterious (0); PolyPhen benign (0.023); catalogued as rs1250312635; called by muse, mutect2, varscan2
- CORO1A | c.88G>A p.V30I | Missense Mutation (SNP) | VAF 181/449 reads (40%) | SIFT tolerated (0.82); PolyPhen benign (0.242); catalogued as rs775464405, COSV99531907; called by muse, mutect2, varscan2
- CRLS1 | c.37del p.A13Pfs*103 | Frame Shift Del (DEL) | VAF 91/265 reads (34%) | catalogued as rs35036314; called by mutect2, pindel, varscan2
- CUL4A | c.766G>A p.V256I (on ENST00000375440 / NM_001008895.4; = p.V156I on NM_003589.3) | Missense Mutation (SNP) | VAF 45/146 reads (31%) | SIFT tolerated (0.16); PolyPhen benign (0.054); catalogued as rs918993044; called by muse, mutect2, varscan2
- DAZAP1 | c.770del p.P257Rfs*78 | Frame Shift Del (DEL) | VAF 37/133 reads (28%) | catalogued as COSV99245498; called by mutect2, pindel, varscan2
- DHRS9 | c.669dup p.L224Tfs*21 | Frame Shift Ins (INS) | VAF 124/302 reads (41%) | catalogued as rs756920263; called by mutect2, varscan2
- DNAH6 | c.10619C>T p.T3540I | Missense Mutation (SNP) | VAF 27/362 reads (7%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.458); catalogued as rs997994912; called by muse, mutect2
- EDA | c.1000C>T p.R334C | Missense Mutation (SNP) | VAF 222/561 reads (40%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.169); catalogued as rs757610457, CD042590; called by muse, mutect2, varscan2
- EDEM2 | c.671G>A p.R224H | Missense Mutation (SNP) | VAF 90/262 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.677); catalogued as rs536739541; called by muse, mutect2, varscan2
- EEF1A1 | c.28A>G p.I10V | Missense Mutation (SNP) | VAF 112/250 reads (45%) | SIFT tolerated, low confidence (0.14); PolyPhen possibly damaging (0.524); catalogued as COSV58550043; called by muse, varscan2
- EGLN2 | c.958G>A p.V320I | Missense Mutation (SNP) | VAF 82/183 reads (45%) | SIFT tolerated (0.28); PolyPhen benign (0.009); catalogued as rs774710749; called by muse, mutect2, varscan2
- EML3 | c.1906G>A p.D636N | Missense Mutation (SNP) | VAF 97/200 reads (49%) | SIFT tolerated (0.32); PolyPhen benign (0.417); catalogued as rs775021776, COSV53870716; called by muse, mutect2, varscan2
- EXT2 | c.29G>A p.R10Q (on ENST00000343631; = p.R43Q on NM_000401.3) | Missense Mutation (SNP) | VAF 149/359 reads (42%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.484); catalogued as rs146906186; called by muse, mutect2, varscan2
- FASN | c.7237C>T p.R2413C | Missense Mutation (SNP) | VAF 176/441 reads (40%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.861); catalogued as rs765469966; called by muse, mutect2, varscan2
- FLNA | c.3973G>A p.E1325K | Missense Mutation (SNP) | VAF 34/387 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.952); catalogued as COSV100774881; called by muse, mutect2
- FYTTD1 | c.365G>A p.R122H | Missense Mutation (SNP) | VAF 81/206 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1560497331, COSV54084803; called by muse, mutect2, varscan2
- GADL1 | c.1065del p.K355Nfs*19 | Frame Shift Del (DEL) | VAF 61/176 reads (35%) | catalogued as COSV56975277; called by mutect2, pindel, varscan2
- GBA | c.236A>G p.Y79C | Missense Mutation (SNP) | VAF 168/883 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1553218329; called by muse, mutect2, varscan2
- GLRA2 | c.754C>T p.R252C | Missense Mutation (SNP) | VAF 109/266 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs748764171; called by muse, mutect2, varscan2
- GRM6 | c.727dup p.V243Gfs*40 | Frame Shift Ins (INS) | VAF 62/167 reads (37%) | catalogued as rs281865186; ClinVar: not provided; called by mutect2, varscan2
- GTF3C4 | c.2128C>T p.R710C | Missense Mutation (SNP) | VAF 106/255 reads (42%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.009); catalogued as rs528646416, COSV100935941; called by muse, mutect2, varscan2
- H2AP | c.94G>A p.V32M | Missense Mutation (SNP) | VAF 177/417 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.661); catalogued as rs1393449126, COSV61911012; called by muse, mutect2, varscan2
- HACD2 | c.266T>C p.L89S | Missense Mutation (SNP) | VAF 14/215 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.196); catalogued as COSV67322291; called by muse, mutect2
- HCN2 | c.2167G>A p.V723I | Missense Mutation (SNP) | VAF 200/466 reads (43%) | SIFT tolerated, low confidence (0.38); PolyPhen benign (0.013); catalogued as rs753793346; ClinVar: uncertain significance; called by muse, varscan2
- HTR1F | c.930del p.F310Lfs*2 | Frame Shift Del (DEL) | VAF 86/207 reads (42%) | catalogued as rs748579647; called by mutect2, varscan2
- INPPL1 | c.683G>A p.G228D | Missense Mutation (SNP) | VAF 96/217 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.922); catalogued as COSV53353158; called by muse, mutect2, varscan2
- JDP2 | c.401G>A p.R134Q | Missense Mutation (SNP) | VAF 168/340 reads (49%) | SIFT tolerated (0.31); PolyPhen benign (0.14); catalogued as rs1332446889; called by muse, mutect2, varscan2
- KANSL1 | c.710T>C p.M237T | Missense Mutation (SNP) | VAF 22/488 reads (5%) | SIFT tolerated (0.97); PolyPhen benign (0); catalogued as rs754918795; called by muse, mutect2
- KAT2B | c.1453G>A p.A485T | Missense Mutation (SNP) | VAF 99/270 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.78); catalogued as COSV55435423; called by muse, mutect2, varscan2
- KAZN | c.73A>G p.N25D | Missense Mutation (SNP) | VAF 146/434 reads (34%) | SIFT tolerated (0.07); PolyPhen benign (0.038); catalogued as rs1166087320, COSV65724173; called by muse, varscan2
- KDM5B | c.1163C>T p.A388V | Missense Mutation (SNP) | VAF 112/492 reads (23%) | SIFT tolerated (0.1); PolyPhen benign (0.096); catalogued as rs61750266; called by muse, mutect2, varscan2
- KIAA2013 | c.268C>T p.P90S | Missense Mutation (SNP) | VAF 24/608 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.941); catalogued as rs1176949043; called by muse, mutect2
- KIF2B | c.626del p.P209Rfs*10 | Frame Shift Del (DEL) | VAF 136/348 reads (39%) | catalogued as COSV52136659; called by mutect2, varscan2
- KLHDC7A | c.383G>A p.G128E | Missense Mutation (SNP) | VAF 192/466 reads (41%) | SIFT tolerated (0.29); PolyPhen benign (0.003); catalogued as COSV68769714; called by muse, mutect2
- KRTAP4-2 | c.350G>A p.R117H | Missense Mutation (SNP) | VAF 233/499 reads (47%) | SIFT tolerated (0.07); PolyPhen benign (0.005); catalogued as rs781168054; called by muse, mutect2, varscan2
- LAMA2 | c.6599G>A p.R2200H | Missense Mutation (SNP) | VAF 76/190 reads (40%) | SIFT tolerated (0.09); PolyPhen probably damaging (1); catalogued as rs779326725, COSV70351053; ClinVar: uncertain significance; called by muse, varscan2
- LGALS4 | c.200G>A p.R67Q | Missense Mutation (SNP) | VAF 148/363 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs772845641; called by muse, mutect2, varscan2
- LHX2 | c.808C>T p.R270C | Missense Mutation (SNP) | VAF 58/452 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65317730; called by muse, mutect2
- LIPC | c.413G>A p.R138H | Missense Mutation (SNP) | VAF 187/458 reads (41%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.467); catalogued as rs376854598; called by muse, mutect2, varscan2
- LRRC32 | c.308G>A p.S103N | Missense Mutation (SNP) | VAF 148/380 reads (39%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1221005538, COSV52632730; called by muse, mutect2, varscan2
- LRRC66 | c.935G>A p.R312H | Missense Mutation (SNP) | VAF 101/315 reads (32%) | SIFT tolerated (0.75); PolyPhen benign (0); catalogued as rs527846401, COSV100602767, COSV58632301; called by muse, mutect2, varscan2
- MAST3 | c.3778C>T p.R1260* | Nonsense Mutation (SNP) | VAF 201/450 reads (45%) | catalogued as COSV53225351; called by muse, mutect2, varscan2
- MEAK7 | c.793C>T p.R265C | Missense Mutation (SNP) | VAF 121/327 reads (37%) | SIFT tolerated (0.09); PolyPhen benign (0.003); catalogued as rs146062987; called by muse, mutect2, varscan2
- MRI1 | c.988del p.H330Tfs*24 (on ENST00000040663 / NM_001031727.4; = p.H283Tfs*24 on NM_032285.4 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 127/356 reads (36%) | catalogued as rs751646149; called by mutect2, pindel, varscan2
- MYLK3 | c.281T>C p.L94P | Missense Mutation (SNP) | VAF 172/463 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs774862265; called by muse, mutect2, varscan2
- NES | c.1176del p.T393Hfs*9 | Frame Shift Del (DEL) | VAF 128/607 reads (21%) | catalogued as rs759081520; called by mutect2, pindel, varscan2
- NOD2 | c.1583dup p.D529Rfs*50 | Frame Shift Ins (INS) | VAF 39/336 reads (12%) | catalogued as rs754073471; ClinVar: uncertain significance; called by mutect2, varscan2
- OR2M7 | c.605G>A p.C202Y | Missense Mutation (SNP) | VAF 131/604 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.976); catalogued as COSV100522605; called by muse, mutect2, varscan2
- OVOL1 | c.749C>T p.A250V | Missense Mutation (SNP) | VAF 178/464 reads (38%) | SIFT tolerated (0.06); PolyPhen benign (0.093); catalogued as rs1430458584; called by muse, varscan2
- PCDHGA1 | c.1778C>T p.A593V | Missense Mutation (SNP) | VAF 179/478 reads (37%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.969); catalogued as rs754685144, COSV65297868; called by muse, mutect2, varscan2
- PCDHGA2 | c.2096C>T p.A699V | Missense Mutation (SNP) | VAF 280/658 reads (43%) | SIFT tolerated, low confidence (0.41); PolyPhen benign (0.012); catalogued as COSV54040233; called by muse, mutect2, varscan2
- PGBD5 | c.784C>T p.R262W (on ENST00000525115; = p.R331W on NM_001258311.2) | Missense Mutation (SNP) | VAF 125/596 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.659); catalogued as rs762626765; called by muse, varscan2
- PIEZO1 | c.6263G>A p.R2088H | Missense Mutation (SNP) | VAF 166/394 reads (42%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.538); catalogued as rs868476887, COSV99966343; called by muse, mutect2, varscan2
- PIGR | c.574C>T p.R192C | Missense Mutation (SNP) | VAF 96/462 reads (21%) | SIFT deleterious (0.04); PolyPhen benign (0.443); catalogued as rs773272615, COSV104423532; called by muse, mutect2, varscan2
- PITPNM3 | c.2452C>T p.R818W | Missense Mutation (SNP) | VAF 155/328 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as rs1459384243, COSV52593161; called by muse, mutect2, varscan2
- PNISR | c.1880G>A p.R627Q | Missense Mutation (SNP) | VAF 66/217 reads (30%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.069); catalogued as rs774652494; called by muse, mutect2, varscan2
- PREX1 | c.2620G>A p.V874M | Missense Mutation (SNP) | VAF 161/364 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); catalogued as rs752025821; called by muse, mutect2, varscan2
- PTPRG | c.278C>A p.A93E | Missense Mutation (SNP) | VAF 95/248 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.536); catalogued as COSV55637474; called by muse, mutect2, varscan2
- RAI2 | c.487G>A p.E163K | Missense Mutation (SNP) | VAF 214/487 reads (44%) | SIFT tolerated (0.92); PolyPhen benign (0.381); catalogued as rs954913951, COSV58963877; called by muse, mutect2, varscan2
- RHCE | c.93dup p.T32Yfs*4 | Frame Shift Ins (INS) | VAF 26/180 reads (14%) | catalogued as rs1361013513; called by mutect2, varscan2
- RILP | c.242C>T p.A81V | Missense Mutation (SNP) | VAF 154/392 reads (39%) | SIFT tolerated (0.09); PolyPhen benign (0.059); catalogued as rs1333104806; called by muse, mutect2, varscan2
- RNF208 | c.407C>T p.A136V | Missense Mutation (SNP) | VAF 174/397 reads (44%) | SIFT tolerated (0.15); PolyPhen benign (0.049); catalogued as rs1487917693; called by muse, varscan2
- RNF43 | c.1189C>T p.R397W | Missense Mutation (SNP) | VAF 175/381 reads (46%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as rs531889929, COSV68460140; called by muse, varscan2
- RPRD2 | c.3209C>G p.S1070C | Missense Mutation (SNP) | VAF 108/550 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.737); catalogued as COSV64818922; called by mutect2, varscan2
- RPTOR | c.3460C>T p.R1154C | Missense Mutation (SNP) | VAF 45/285 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.641); catalogued as rs750857501; called by muse, mutect2, varscan2
- SEC14L5 | c.1863dup p.S622Qfs*31 | Frame Shift Ins (INS) | VAF 132/367 reads (36%) | catalogued as rs764657044; called by mutect2, varscan2
- SETD2 | c.4786T>C p.Y1596H | Missense Mutation (SNP) | VAF 119/241 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100338302; called by muse, mutect2, varscan2
- SEZ6L2 | c.281G>A p.R94Q | Missense Mutation (SNP) | VAF 182/412 reads (44%) | SIFT tolerated (0.51); PolyPhen benign (0.039); catalogued as rs1330909596, COSV100435731; called by muse, mutect2, varscan2
- SLC2A5 | c.1247dup p.S417Qfs*64 | Frame Shift Ins (INS) | VAF 114/341 reads (33%) | catalogued as rs1223118492; called by mutect2, pindel, varscan2
- SNAPC4 | c.4004del p.G1335Afs*72 | Frame Shift Del (DEL) | VAF 200/556 reads (36%) | catalogued as rs749900519; called by mutect2, pindel, varscan2
- SNAPC4 | c.2869G>C p.A957P | Missense Mutation (SNP) | VAF 192/405 reads (47%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as rs575245185; called by muse, mutect2, varscan2
- SPAG4 | c.1178del p.P393Qfs*7 | Frame Shift Del (DEL) | VAF 83/236 reads (35%) | catalogued as rs1292316291; called by mutect2, pindel, varscan2
- SPEM1 | c.38C>T p.S13L | Missense Mutation (SNP) | VAF 122/265 reads (46%) | SIFT tolerated (0.17); PolyPhen benign (0.013); catalogued as rs1291482484; called by muse, varscan2
- SPTBN4 | c.5566C>T p.R1856W | Missense Mutation (SNP) | VAF 170/420 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs368152529; called by muse, mutect2, varscan2
- TAF1 | c.1735C>T p.R579W (on ENST00000373790 / NM_138923.4; = p.R600W on NM_004606.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 102/273 reads (37%) | SIFT tolerated (0.06); PolyPhen benign (0.015); catalogued as rs1234786163, COSV99335953; called by muse, mutect2, varscan2
- TAF1C | c.2116C>T p.P706S | Missense Mutation (SNP) | VAF 160/367 reads (44%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as COSV58985932; called by muse, mutect2, varscan2
- TCHH | c.5513G>A p.R1838Q | Missense Mutation (SNP) | VAF 172/757 reads (23%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.168); catalogued as COSV64274051; called by muse, mutect2, varscan2
- THOP1 | c.1627C>T p.R543W | Missense Mutation (SNP) | VAF 112/304 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1048224954; called by muse, mutect2, varscan2
- TMEM94 | c.2497G>A p.A833T | Missense Mutation (SNP) | VAF 161/372 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1229354895; called by muse, mutect2, varscan2
- TRANK1 | c.2666G>A p.R889Q | Missense Mutation (SNP) | VAF 38/377 reads (10%) | SIFT tolerated (0.07); PolyPhen benign (0.007); catalogued as rs764907227; called by muse, mutect2, varscan2
- TRAV30 | c.266del p.K89Sfs*? | Frame Shift Del (DEL) | VAF 96/252 reads (38%) | catalogued as rs373076040; called by mutect2, varscan2
- TRPS1 | c.14A>G p.K5R (on ENST00000220888 / NM_001330599.2; = p.K18R on NM_014112.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 28/321 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.971); catalogued as COSV55257319; called by muse, mutect2
- TTBK2 | c.3278G>A p.R1093H | Missense Mutation (SNP) | VAF 12/130 reads (9%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as rs1367109204; called by muse, mutect2
- UHRF1 | c.619C>T p.R207C (on ENST00000612630 / NM_001290050.1; = p.R220C on NM_013282.4) | Missense Mutation (SNP) | VAF 32/474 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs748641020; called by muse, mutect2
- URGCP | c.923C>T p.S308L (on ENST00000453200 / NM_001077663.3; = p.S299L on NM_017920.4) | Missense Mutation (SNP) | VAF 119/324 reads (37%) | SIFT deleterious (0); PolyPhen benign (0.336); catalogued as COSV56253324; called by muse, varscan2
- UTF1 | c.271G>A p.A91T | Missense Mutation (SNP) | VAF 49/556 reads (9%) | SIFT tolerated (0.06); PolyPhen benign (0.022); catalogued as rs932347781; called by muse, mutect2
- WDR7 | c.50C>T p.A17V | Missense Mutation (SNP) | VAF 51/334 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs1168048508; called by muse, mutect2, varscan2
- WFIKKN1 | c.1058G>A p.R353H | Missense Mutation (SNP) | VAF 69/501 reads (14%) | SIFT tolerated (0.13); PolyPhen benign (0.226); catalogued as rs751410634, COSV50194979; called by muse, mutect2, varscan2
- WIZ | c.2613del p.S872Afs*15 (on ENST00000673675 / NM_001371589.1; = p.S135Afs*15 on NM_021241.3) | Frame Shift Del (DEL) | VAF 197/512 reads (38%) | catalogued as COSV54610544; called by mutect2, pindel, varscan2
- WNK4 | c.1822del p.V608Cfs*53 | Frame Shift Del (DEL) | VAF 179/536 reads (33%) | catalogued as rs762079039; called by mutect2, pindel, varscan2
- WNT7B | c.35T>C p.V12A | Missense Mutation (SNP) | VAF 48/372 reads (13%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as rs1395135256, COSV59751138; called by muse, mutect2, varscan2
- XYLT1 | c.2287A>G p.M763V | Missense Mutation (SNP) | VAF 147/355 reads (41%) | SIFT tolerated (0.31); PolyPhen benign (0.171); catalogued as rs145121977; called by muse, mutect2, varscan2
- ZBTB22 | c.1263G>A p.M421I | Missense Mutation (SNP) | VAF 257/592 reads (43%) | SIFT tolerated (0.09); PolyPhen benign (0.014); catalogued as COSV99801256; called by muse, mutect2, varscan2
- ZNF124 | c.1015dup p.T339Nfs*9 (on ENST00000543802 / NM_001297568.1; = p.T277Nfs*9 on NM_003431.5 and 1 other RefSeq transcript) | Frame Shift Ins (INS) | VAF 105/460 reads (23%) | catalogued as rs746309323; called by mutect2, varscan2
- ZNF524 | c.174del p.K59Sfs*14 | Frame Shift Del (DEL) | VAF 180/420 reads (43%) | catalogued as rs750719825; called by mutect2, varscan2
- ZNF536 | c.268C>T p.R90W | Missense Mutation (SNP) | VAF 167/376 reads (44%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as rs1462410123, COSV62822885, COSV62828065; called by muse, varscan2
- ZSCAN26 | c.1294C>T p.R432* (on ENST00000623276 / NM_001111039.2; = p.R298* on NM_152736.5) | Nonsense Mutation (SNP) | VAF 99/234 reads (42%) | catalogued as rs757181763; called by muse, mutect2, varscan2
- ABCC12 | c.2435G>A p.S812N | Missense Mutation (SNP) | VAF 38/314 reads (12%) | SIFT tolerated (0.26); PolyPhen benign (0.177); called by muse, mutect2, varscan2
- ABL1 | c.1054G>T p.E352* | Nonsense Mutation (SNP) | VAF 13/282 reads (5%) | called by muse, mutect2
- ACAP1 | c.491C>T p.A164V | Missense Mutation (SNP) | VAF 12/408 reads (3%) | SIFT deleterious (0.01); PolyPhen benign (0); called by muse, mutect2
- ACE2 | c.2161A>G p.S721G | Missense Mutation (SNP) | VAF 24/532 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.08); called by muse, mutect2
- ADAL | c.651del p.E218Kfs*33 | Frame Shift Del (DEL) | VAF 68/149 reads (46%) | called by mutect2, varscan2
- ADAM28 | c.223_224dup p.N75Kfs*54 | Frame Shift Ins (INS) | VAF 30/112 reads (27%) | called by mutect2, varscan2
- ADAR | c.2185G>T p.G729C | Missense Mutation (SNP) | VAF 147/635 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ADCY6 | c.1034T>C p.V345A | Missense Mutation (SNP) | VAF 34/288 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.698); called by muse, mutect2, varscan2
- ADHFE1 | c.1178C>T p.T393I | Missense Mutation (SNP) | VAF 40/254 reads (16%) | SIFT tolerated (0.32); PolyPhen benign (0.435); called by muse, mutect2, varscan2
- ADRB1 | c.1238G>A p.G413D | Missense Mutation (SNP) | VAF 203/454 reads (45%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- AFG3L2 | c.2375del p.G792Vfs*49 | Frame Shift Del (DEL) | VAF 91/252 reads (36%) | called by mutect2, pindel, varscan2
- AGRN | c.65G>A p.C22Y | Missense Mutation (SNP) | VAF 24/536 reads (4%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.029); called by muse, mutect2
- AMER1 | c.2060C>G p.T687S | Missense Mutation (SNP) | VAF 172/440 reads (39%) | SIFT tolerated (0.26); PolyPhen benign (0); called by muse, varscan2
- ANKRD23 | c.886G>A p.A296T | Missense Mutation (SNP) | VAF 12/400 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); called by muse, mutect2
- AOC1 | c.1192C>A p.L398M | Missense Mutation (SNP) | VAF 193/424 reads (46%) | SIFT deleterious (0.04); PolyPhen benign (0.43); called by muse, mutect2, varscan2
- AP2A1 | c.1595T>C p.L532P | Missense Mutation (SNP) | VAF 13/388 reads (3%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); called by muse, mutect2
- AQR | c.3919G>C p.V1307L | Missense Mutation (SNP) | VAF 127/294 reads (43%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.528); called by muse, mutect2, varscan2
- ARHGAP33 | c.1706C>G p.A569G | Missense Mutation (SNP) | VAF 43/329 reads (13%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0.022); called by muse, mutect2, varscan2
- ARHGEF5 | c.4735C>A p.L1579M | Missense Mutation (SNP) | VAF 87/244 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); called by muse, mutect2, varscan2
- ARMH3 | c.1673T>C p.M558T | Missense Mutation (SNP) | VAF 91/214 reads (43%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.765); called by muse, mutect2, varscan2
- ATG9A | c.464G>A p.C155Y | Missense Mutation (SNP) | VAF 115/356 reads (32%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.795); called by muse, mutect2, varscan2
- BNIP2 | c.456del p.V153Lfs*12 | Frame Shift Del (DEL) | VAF 67/193 reads (35%) | called by mutect2, pindel, varscan2
- BNIP3 | c.582del p.K195Rfs*16 | Frame Shift Del (DEL) | VAF 101/320 reads (32%) | called by mutect2, pindel, varscan2
- BROX | c.289C>T p.Q97* | Nonsense Mutation (SNP) | VAF 90/385 reads (23%) | called by muse, mutect2, varscan2
- BTBD18 | c.175_177del p.F59del | In Frame Del (DEL) | VAF 86/282 reads (30%) | called by pindel, varscan2
- CACNB1 | c.710C>T p.P237L | Missense Mutation (SNP) | VAF 120/266 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, varscan2
- CAMSAP1 | c.1496T>C p.I499T | Missense Mutation (SNP) | VAF 151/342 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- CASZ1 | c.4979G>A p.R1660H | Missense Mutation (SNP) | VAF 58/130 reads (45%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0); called by muse, varscan2
- CCDC144A | c.1205A>G p.D402G | Missense Mutation (SNP) | VAF 85/233 reads (36%) | SIFT tolerated (0.24); PolyPhen benign (0.063); called by muse, mutect2, varscan2
- CCDC186 | c.842del p.N281Mfs*32 | Frame Shift Del (DEL) | VAF 95/254 reads (37%) | called by mutect2, pindel, varscan2
- CCDC51 | c.527G>A p.R176Q | Missense Mutation (SNP) | VAF 118/254 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CDKN1C | c.446C>A p.P149H | Missense Mutation (SNP) | VAF 236/500 reads (47%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.035); called by muse, mutect2, varscan2
- CEACAM20 | c.368T>C p.L123P | Missense Mutation (SNP) | VAF 26/456 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- CEP192 | c.7476-1G>A p.X2492_splice | Splice Site (SNP) | VAF 54/143 reads (38%) | called by muse, varscan2
- CFAP91 | c.1483G>A p.A495T | Missense Mutation (SNP) | VAF 74/183 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CHD6 | c.3772A>G p.R1258G | Missense Mutation (SNP) | VAF 114/254 reads (45%) | SIFT tolerated (0.09); PolyPhen benign (0.416); called by muse, mutect2, varscan2
- CHRNA1 | c.1271T>A p.I424N (on ENST00000261007 / NM_001039523.3; = p.I399N on NM_000079.4) | Missense Mutation (SNP) | VAF 116/280 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.701); called by mutect2, varscan2
- COASY | c.380A>G p.N127S | Missense Mutation (SNP) | VAF 20/509 reads (4%) | SIFT tolerated (0.19); PolyPhen benign (0.041); called by muse, mutect2
- COG7 | c.865G>A p.A289T | Missense Mutation (SNP) | VAF 137/345 reads (40%) | SIFT tolerated (0.23); PolyPhen benign (0.227); called by muse, mutect2, varscan2
- COL17A1 | c.3794G>C p.G1265A | Missense Mutation (SNP) | VAF 106/290 reads (37%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.973); called by muse, varscan2
- COL20A1 | c.2098G>T p.G700C | Missense Mutation (SNP) | VAF 37/496 reads (7%) | SIFT tolerated (0.24); PolyPhen benign (0.111); called by muse, mutect2
- COL5A1 | c.4941del p.D1648Tfs*81 | Frame Shift Del (DEL) | VAF 107/291 reads (37%) | called by mutect2, pindel, varscan2
- CRNN | c.559G>T p.G187W | Missense Mutation (SNP) | VAF 147/672 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- CSNK1A1 | c.1006G>T p.G336C | Missense Mutation (SNP) | VAF 40/224 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.965); called by mutect2, varscan2
- CSRNP2 | c.332C>T p.A111V | Missense Mutation (SNP) | VAF 90/283 reads (32%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); called by muse, varscan2
- CTCF | c.1430A>T p.H477L | Missense Mutation (SNP) | VAF 110/294 reads (37%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.969); called by muse, varscan2
- DEPDC5 | c.1508G>A p.S503N | Missense Mutation (SNP) | VAF 138/358 reads (39%) | SIFT tolerated (0.41); PolyPhen benign (0.113); called by muse, mutect2, varscan2
- DLGAP4 | c.1241G>T p.R414M | Missense Mutation (SNP) | VAF 22/334 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.007); called by muse, mutect2
- DNAH10 | c.3417del p.E1140Rfs*42 (on ENST00000409039; = p.E1079Rfs*42 on NM_207437.3) | Frame Shift Del (DEL) | VAF 82/250 reads (33%) | called by mutect2, pindel, varscan2
- DNAH17 | c.10141T>A p.F3381I | Missense Mutation (SNP) | VAF 106/235 reads (45%) | SIFT tolerated (0.42); PolyPhen benign (0.038); called by muse, mutect2, varscan2
- DNHD1 | c.779A>C p.K260T | Missense Mutation (SNP) | VAF 41/276 reads (15%) | SIFT deleterious (0.03); PolyPhen benign (0.049); called by muse, mutect2, varscan2
- E2F1 | c.452T>A p.V151D | Missense Mutation (SNP) | VAF 142/340 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, varscan2
- E2F1 | c.49G>T p.E17* | Nonsense Mutation (SNP) | VAF 168/354 reads (47%) | called by muse, mutect2, varscan2
- ELF1 | c.226G>A p.D76N | Missense Mutation (SNP) | VAF 112/256 reads (44%) | SIFT tolerated (0.35); PolyPhen benign (0.127); called by muse, mutect2
- ELOB | c.262_263del p.L88Vfs*26 | Frame Shift Del (DEL) | VAF 73/282 reads (26%) | called by mutect2, pindel, varscan2
- ENTPD6 | c.139del p.L47Wfs*84 | Frame Shift Del (DEL) | VAF 114/365 reads (31%) | called by mutect2, pindel, varscan2
- F2RL2 | c.349T>C p.W117R | Missense Mutation (SNP) | VAF 121/332 reads (36%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.961); called by muse, varscan2
- FADS1 | c.296T>C p.V99A | Missense Mutation (SNP) | VAF 15/519 reads (3%) | SIFT deleterious (0.04); PolyPhen benign (0.034); called by muse, mutect2
- FAM186B | c.1214T>C p.F405S | Missense Mutation (SNP) | VAF 99/272 reads (36%) | SIFT deleterious (0.05); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- FEZ2 | c.83del p.A28Gfs*31 | Frame Shift Del (DEL) | VAF 40/392 reads (10%) | called by mutect2, pindel, varscan2
- FPR1 | c.464T>C p.L155P | Missense Mutation (SNP) | VAF 116/296 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.934); called by muse, varscan2
- GAB4 | c.620C>A p.P207H | Missense Mutation (SNP) | VAF 151/395 reads (38%) | SIFT deleterious (0.02); PolyPhen benign (0.395); called by muse, mutect2, varscan2
- GATA6 | c.1120C>T p.R374W | Missense Mutation (SNP) | VAF 140/340 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.904); called by muse, varscan2
- GDPD3 | c.46G>A p.A16T | Missense Mutation (SNP) | VAF 138/344 reads (40%) | SIFT tolerated (0.24); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- GEN1 | c.1256A>G p.E419G | Missense Mutation (SNP) | VAF 50/120 reads (42%) | SIFT deleterious (0.03); PolyPhen benign (0.035); called by muse, varscan2
- GFOD1 | c.647C>T p.T216I | Missense Mutation (SNP) | VAF 31/325 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); called by muse, mutect2, varscan2
- GHITM | c.712A>C p.S238R | Missense Mutation (SNP) | VAF 117/294 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); called by muse, varscan2
- GPRIN1 | c.808T>C p.S270P | Missense Mutation (SNP) | VAF 107/289 reads (37%) | SIFT deleterious (0.02); PolyPhen benign (0.194); called by muse, mutect2, varscan2
- GPSM1 | c.1571C>T p.A524V | Missense Mutation (SNP) | VAF 164/376 reads (44%) | SIFT tolerated (0.36); PolyPhen benign (0.192); called by muse, varscan2
- GRAMD1B | c.405G>T p.W135C | Missense Mutation (SNP) | VAF 112/266 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- GRHL2 | c.1876T>C p.*626Qext*67 | Nonstop Mutation (SNP) | VAF 16/341 reads (5%) | called by muse, mutect2
- GRIN2B | c.3926A>G p.D1309G | Missense Mutation (SNP) | VAF 169/410 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.93); called by muse, mutect2, varscan2
- GTF2I | c.1952C>T p.S651F (on ENST00000573035 / NM_032999.4; = p.S610F on NM_001518.5) | Missense Mutation (SNP) | VAF 52/151 reads (34%) | SIFT deleterious (0.01); PolyPhen benign (0.178); called by muse, varscan2
- HAS1 | c.44G>A p.R15H | Missense Mutation (SNP) | VAF 106/323 reads (33%) | SIFT tolerated (0.47); PolyPhen benign (0); called by muse, mutect2, varscan2
- HAUS3 | c.713T>C p.F238S | Missense Mutation (SNP) | VAF 76/208 reads (37%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.712); called by muse, mutect2, varscan2
- HMCN1 | c.9490A>G p.T3164A | Missense Mutation (SNP) | VAF 78/384 reads (20%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- HNRNPD | c.555dup p.V186Cfs*10 | Frame Shift Ins (INS) | VAF 138/409 reads (34%) | called by mutect2, pindel, varscan2
- HOXA10 | c.156_161del p.G55_G56del | In Frame Del (DEL) | VAF 171/474 reads (36%) | called by mutect2, pindel, varscan2
- HSPA12B | c.1738G>A p.A580T | Missense Mutation (SNP) | VAF 224/496 reads (45%) | SIFT tolerated (0.34); PolyPhen benign (0.131); called by muse, mutect2, varscan2
- IFI6 | c.169C>T p.P57S | Missense Mutation (SNP) | VAF 199/505 reads (39%) | SIFT tolerated (0.06); PolyPhen benign (0.399); called by muse, mutect2, varscan2
- IFIT5 | c.192del p.G65Afs*16 | Frame Shift Del (DEL) | VAF 86/225 reads (38%) | called by mutect2, varscan2
- IGF2R | c.6310G>A p.A2104T | Missense Mutation (SNP) | VAF 88/196 reads (45%) | SIFT tolerated (0.74); PolyPhen benign (0); called by muse, mutect2, varscan2
- INPPL1 | c.1414C>T p.Q472* | Nonsense Mutation (SNP) | VAF 143/351 reads (41%) | called by muse, mutect2, varscan2
- INPPL1 | c.1981T>C p.Y661H | Missense Mutation (SNP) | VAF 73/279 reads (26%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.794); called by muse, mutect2
- INTS6 | c.560C>A p.T187K | Missense Mutation (SNP) | VAF 127/274 reads (46%) | SIFT deleterious (0.03); PolyPhen benign (0.315); called by muse, mutect2, varscan2
- KATNAL2 | c.105T>A p.H35Q | Missense Mutation (SNP) | VAF 101/229 reads (44%) | SIFT tolerated (0.58); PolyPhen benign (0.071); called by muse, mutect2, varscan2
- KBTBD11 | c.1408C>A p.L470M | Missense Mutation (SNP) | VAF 67/506 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- KCNA5 | c.560G>T p.R187M | Missense Mutation (SNP) | VAF 209/460 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); called by muse, mutect2, varscan2
- KMT2D | c.2993dup p.M999Yfs*69 | Frame Shift Ins (INS) | VAF 120/447 reads (27%) | called by pindel, varscan2
- KNL1 | c.2188dup p.S730Ffs*11 (on ENST00000346991 / NM_170589.5; = p.S704Ffs*11 on NM_144508.5) | Frame Shift Ins (INS) | VAF 31/254 reads (12%) | called by mutect2, pindel, varscan2
- KRTAP5-1 | c.245del p.C82Lfs*? | Frame Shift Del (DEL) | VAF 59/160 reads (37%) | called by mutect2, pindel, varscan2
- LOX | c.1199T>G p.I400S | Missense Mutation (SNP) | VAF 104/236 reads (44%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.525); called by muse, mutect2, varscan2
- LRFN3 | c.1349C>A p.P450H | Missense Mutation (SNP) | VAF 164/446 reads (37%) | SIFT tolerated (0.77); PolyPhen benign (0.036); called by muse, mutect2, varscan2
- LUC7L2 | c.206C>T p.A69V | Missense Mutation (SNP) | VAF 71/214 reads (33%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.993); called by muse, varscan2
- LZTS3 | c.1527A>T p.E509D (on ENST00000329152; = p.E463D on NM_001282533.2) | Missense Mutation (SNP) | VAF 199/466 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- MAN2A1 | c.960del p.K320Nfs*29 | Frame Shift Del (DEL) | VAF 108/330 reads (33%) | called by mutect2, pindel, varscan2
- MAP3K9 | c.617T>C p.L206P | Missense Mutation (SNP) | VAF 42/449 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- MAPKAPK5 | c.154del p.I52Ffs*16 | Frame Shift Del (DEL) | VAF 109/305 reads (36%) | called by mutect2, pindel, varscan2
- MARVELD2 | c.334G>T p.G112* | Nonsense Mutation (SNP) | VAF 49/577 reads (8%) | called by muse, mutect2
- MCMBP | c.1601A>G p.E534G | Missense Mutation (SNP) | VAF 16/414 reads (4%) | SIFT deleterious (0.01); PolyPhen benign (0.212); called by muse, mutect2
- MEAK7 | c.1342G>T p.G448W | Missense Mutation (SNP) | VAF 176/384 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MED23 | c.1460G>T p.C487F | Missense Mutation (SNP) | VAF 92/234 reads (39%) | SIFT tolerated (0.49); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- MFNG | c.194C>A p.A65D | Missense Mutation (SNP) | VAF 144/370 reads (39%) | SIFT deleterious (0.01); PolyPhen benign (0.322); called by muse, mutect2, varscan2
- MIA3 | c.4588_4590del p.K1530del | In Frame Del (DEL) | VAF 69/446 reads (15%) | called by mutect2, pindel, varscan2
- MICU3 | c.587C>T p.A196V | Missense Mutation (SNP) | VAF 92/195 reads (47%) | SIFT tolerated (0.3); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- MPLKIP | c.227dup p.R77Pfs*52 | Frame Shift Ins (INS) | VAF 184/537 reads (34%) | called by mutect2, pindel, varscan2
- MRGBP | c.19G>T p.G7C | Missense Mutation (SNP) | VAF 141/360 reads (39%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.506); called by muse, mutect2, varscan2
- MTHFR | c.935G>A p.S312N | Missense Mutation (SNP) | VAF 114/292 reads (39%) | SIFT tolerated (0.29); PolyPhen benign (0.038); called by muse, varscan2
- MVB12B | c.62C>T p.P21L | Missense Mutation (SNP) | VAF 132/307 reads (43%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.913); called by muse, mutect2, varscan2
- MYADML2 | c.74C>T p.A25V | Missense Mutation (SNP) | VAF 19/428 reads (4%) | SIFT tolerated (1); PolyPhen benign (0.007); called by muse, mutect2
- MYO9B | c.6437A>G p.Y2146C | Missense Mutation (SNP) | VAF 15/442 reads (3%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- MYOM1 | c.1957T>C p.Y653H | Missense Mutation (SNP) | VAF 15/296 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- NAB2 | c.778del p.D260Mfs*9 | Frame Shift Del (DEL) | VAF 132/387 reads (34%) | called by mutect2, pindel, varscan2
- NIN | c.1970G>T p.R657M | Missense Mutation (SNP) | VAF 97/266 reads (36%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.525); called by mutect2, varscan2
- NRBP2 | c.509del p.P170Qfs*7 | Frame Shift Del (DEL) | VAF 110/330 reads (33%) | called by mutect2, pindel, varscan2
- NRF1 | c.1406_1412del p.G469Dfs*10 | Frame Shift Del (DEL) | VAF 145/368 reads (39%) | called by mutect2, pindel, varscan2
- P2RX5 | c.689C>A p.P230H | Missense Mutation (SNP) | VAF 123/304 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, varscan2
- PAPPA2 | c.1183del p.L395* | Frame Shift Del (DEL) | VAF 160/759 reads (21%) | called by mutect2, pindel, varscan2
- PELO | c.1055C>G p.S352C | Missense Mutation (SNP) | VAF 116/273 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PHF21A | c.1975A>G p.T659A (on ENST00000418153 / NM_001101802.3; = p.T613A on NM_016621.5 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 124/336 reads (37%) | SIFT tolerated, low confidence (0.51); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- PJA2 | c.764A>G p.E255G | Missense Mutation (SNP) | VAF 113/295 reads (38%) | SIFT tolerated (0.31); PolyPhen benign (0); called by muse, mutect2, varscan2
- PLIN4 | c.3412C>G p.L1138V (on ENST00000301286; = p.L1153V on NM_001367868.2) | Missense Mutation (SNP) | VAF 124/355 reads (35%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.926); called by muse, mutect2, varscan2
- PMEL | c.1880T>C p.V627A | Missense Mutation (SNP) | VAF 13/312 reads (4%) | SIFT tolerated (0.81); PolyPhen benign (0.007); called by muse, mutect2
- POLI | c.16del p.V6Wfs*50 | Frame Shift Del (DEL) | VAF 129/288 reads (45%) | called by mutect2, pindel, varscan2
- PROS1 | c.1733G>A p.R578K | Missense Mutation (SNP) | VAF 74/216 reads (34%) | SIFT tolerated (0.9); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- PRRT4 | c.2117C>T p.P706L | Missense Mutation (SNP) | VAF 213/540 reads (39%) | SIFT tolerated (0.28); PolyPhen benign (0.027); called by muse, varscan2
- PTPN14 | c.972G>C p.W324C | Missense Mutation (SNP) | VAF 115/497 reads (23%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.862); called by muse, mutect2
- PXDN | c.2141T>C p.L714P | Missense Mutation (SNP) | VAF 102/239 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- RAPGEF5 | c.1736G>T p.R579L (on ENST00000401957 / NM_001367602.2; = p.R882L on NM_012294.5) | Missense Mutation (SNP) | VAF 12/246 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); called by muse, mutect2
- RGMB | c.1186G>A p.E396K (on ENST00000513185 / NM_001366508.1; = p.E437K on NM_001012761.3 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 158/352 reads (45%) | SIFT tolerated (1); PolyPhen benign (0.04); called by muse, mutect2, varscan2
- RNF31 | c.2828A>G p.Q943R | Missense Mutation (SNP) | VAF 14/234 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.255); called by muse, mutect2
- RRN3 | c.1637_1671del p.G546Dfs*6 | Frame Shift Del (DEL) | VAF 74/385 reads (19%) | called by mutect2, pindel, varscan2
- SEPTIN9 | c.1679A>G p.Y560C (on ENST00000427177 / NM_001113491.2; = p.Y542C on NM_006640.4) | Missense Mutation (SNP) | VAF 16/301 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- SERTAD3 | c.237del p.E80Sfs*37 | Frame Shift Del (DEL) | VAF 35/323 reads (11%) | called by mutect2, pindel, varscan2
- SH3TC2 | c.2929C>T p.P977S | Missense Mutation (SNP) | VAF 63/335 reads (19%) | SIFT tolerated (0.73); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- SHROOM1 | c.1944G>T p.Q648H | Missense Mutation (SNP) | VAF 124/282 reads (44%) | SIFT deleterious (0.05); PolyPhen benign (0.275); called by muse, mutect2, varscan2
- SLC23A3 | c.1283T>C p.L428P (on ENST00000409878 / NM_001144889.2; = p.L311P on NM_144712.5) | Missense Mutation (SNP) | VAF 98/229 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- SLC9A3R1 | c.260G>T p.R87L | Missense Mutation (SNP) | VAF 177/402 reads (44%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.517); called by muse, varscan2
- SLC9A5 | c.654G>A p.V218= | Splice Region (SNP) | VAF 75/190 reads (39%) | called by muse, mutect2, varscan2
- SNX2 | c.1162_1163del p.M388Vfs*6 | Frame Shift Del (DEL) | VAF 104/320 reads (33%) | called by pindel, varscan2
- SORBS1 | c.580G>A p.A194T (on ENST00000361941 / NM_001034954.2; = p.A162T on NM_015385.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 16/334 reads (5%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.024); called by muse, mutect2
- SOX9 | c.1049del p.P350Hfs*33 | Frame Shift Del (DEL) | VAF 182/462 reads (39%) | called by mutect2, pindel, varscan2
- SP9 | c.879del p.S294Afs*56 | Frame Shift Del (DEL) | VAF 131/352 reads (37%) | called by mutect2, pindel, varscan2
- SVEP1 | c.6049C>A p.L2017M | Missense Mutation (SNP) | VAF 28/314 reads (9%) | SIFT tolerated (0.11); PolyPhen benign (0.044); called by muse, mutect2
- SVEP1 | c.3264del p.C1089Vfs*8 | Frame Shift Del (DEL) | VAF 110/311 reads (35%) | called by mutect2, pindel, varscan2
- SYNJ2 | c.2810T>C p.V937A | Missense Mutation (SNP) | VAF 12/317 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- TACC2 | c.5464_5465del p.X1822_splice | Splice Site (DEL) | VAF 60/174 reads (34%) | called by pindel, varscan2
- TBC1D9 | c.393_401del p.D131_K133del | In Frame Del (DEL) | VAF 82/242 reads (34%) | called by mutect2, pindel, varscan2
- TLX2 | c.671G>A p.R224Q | Missense Mutation (SNP) | VAF 166/395 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); called by muse, mutect2, varscan2
- TMEM121 | c.329G>A p.R110H | Missense Mutation (SNP) | VAF 207/509 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); called by muse, mutect2, varscan2
- TNRC6B | c.2125T>C p.W709R | Missense Mutation (SNP) | VAF 43/305 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- TRDMT1 | c.851A>G p.Q284R | Missense Mutation (SNP) | VAF 82/210 reads (39%) | SIFT tolerated (0.21); PolyPhen benign (0); called by muse, mutect2, varscan2
- TRIM3 | c.40C>T p.P14S | Missense Mutation (SNP) | VAF 111/279 reads (40%) | SIFT deleterious (0.03); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- TRIM64B | c.313G>A p.A105T | Missense Mutation (SNP) | VAF 31/318 reads (10%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.825); called by muse, mutect2, varscan2
- TRIO | c.3299C>G p.T1100R | Missense Mutation (SNP) | VAF 55/161 reads (34%) | SIFT tolerated (0.06); PolyPhen benign (0.185); called by muse, varscan2
- TRIO | c.3728A>G p.E1243G | Missense Mutation (SNP) | VAF 34/367 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- TSSK3 | c.619A>G p.S207G | Missense Mutation (SNP) | VAF 18/424 reads (4%) | SIFT tolerated (0.16); PolyPhen benign (0.088); called by muse, mutect2
- TTLL4 | c.3471C>A p.D1157E | Missense Mutation (SNP) | VAF 172/409 reads (42%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- TUT4 | c.1663G>A p.D555N | Missense Mutation (SNP) | VAF 62/262 reads (24%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- TXNDC12 | c.329del p.G110Vfs*42 | Frame Shift Del (DEL) | VAF 128/329 reads (39%) | called by mutect2, pindel, varscan2
- UBA7 | c.1697G>C p.G566A | Missense Mutation (SNP) | VAF 49/333 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- UFSP1 | c.170del p.G57Vfs*23 | Frame Shift Del (DEL) | VAF 152/403 reads (38%) | called by mutect2, pindel, varscan2
- USF3 | c.6683G>A p.R2228K | Missense Mutation (SNP) | VAF 112/313 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- USP45 | c.345T>A p.C115* | Nonsense Mutation (SNP) | VAF 106/255 reads (42%) | called by muse, mutect2
- VPS8 | c.1361C>T p.S454L (on ENST00000625842 / NM_001349294.1; = p.S452L on NM_015303.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 112/261 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); called by muse, mutect2, varscan2
- WDFY4 | c.2584A>G p.S862G | Missense Mutation (SNP) | VAF 124/266 reads (47%) | SIFT tolerated (0.2); PolyPhen benign (0); called by muse, mutect2, varscan2
- WDR36 | c.1099G>T p.G367C | Missense Mutation (SNP) | VAF 69/162 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, varscan2
- WRNIP1 | c.1625T>C p.F542S | Missense Mutation (SNP) | VAF 25/227 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.561); called by muse, mutect2, varscan2
- XKR6 | c.615del p.M206* | Frame Shift Del (DEL) | VAF 139/494 reads (28%) | called by mutect2, pindel, varscan2
- ZCCHC2 | c.2216C>T p.A739V | Missense Mutation (SNP) | VAF 143/360 reads (40%) | SIFT tolerated (0.17); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- ZDHHC7 | c.161C>T p.T54M | Missense Mutation (SNP) | VAF 29/445 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- ZFAND3 | c.524G>A p.R175H | Missense Mutation (SNP) | VAF 18/181 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ZFHX3 | c.530_555del p.A177Vfs*24 | Frame Shift Del (DEL) | VAF 121/417 reads (29%) | called by mutect2, pindel, varscan2
- ZMYM4 | c.2262A>G p.E754= | Splice Region (SNP) | VAF 51/138 reads (37%) | called by muse, mutect2, varscan2
- ZNF263 | c.1247G>A p.G416D | Missense Mutation (SNP) | VAF 136/302 reads (45%) | SIFT tolerated (0.46); PolyPhen benign (0.036); called by muse, varscan2
- ZNF551 | c.413T>C p.M138T | Missense Mutation (SNP) | VAF 32/393 reads (8%) | SIFT tolerated (0.69); PolyPhen benign (0); called by muse, mutect2
- ZNF608 | c.4452C>A p.G1484= | Splice Region (SNP) | VAF 75/247 reads (30%) | called by muse, mutect2, varscan2
- ZNF683 | c.431G>T p.G144V | Missense Mutation (SNP) | VAF 32/435 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.92); called by muse, mutect2
- ZNF790 | c.812T>C p.V271A | Missense Mutation (SNP) | VAF 10/339 reads (3%) | SIFT tolerated (0.34); PolyPhen benign (0.33); called by muse, mutect2
- ABR | c.774T>C p.P258= (on ENST00000302538 / NM_021962.5; = p.P221= on NM_001092.5) | Silent (SNP) | VAF 34/500 reads (7%) | called by muse, mutect2
- ACCS | c.1293C>G p.L431= | Silent (SNP) | VAF 154/324 reads (48%) | called by muse, varscan2
- ACO2 | c.261G>A p.S87= | Silent (SNP) | VAF 159/406 reads (39%) | catalogued as rs748850283; called by muse, mutect2, varscan2
- ACR | c.72G>A p.T24= | Silent (SNP) | VAF 22/283 reads (8%) | catalogued as rs151269264, COSV99334539; called by muse, mutect2
- ADAMTS14 | c.3258C>T p.H1086= | Silent (SNP) | VAF 165/426 reads (39%) | called by muse, mutect2, varscan2
- ADAMTS16 | c.301C>T p.L101= | Silent (SNP) | VAF 116/266 reads (44%) | called by muse, varscan2
- ADAMTS4 | c.2310A>G p.T770= | Silent (SNP) | VAF 146/608 reads (24%) | called by muse, varscan2
- AQP8 | c.219G>A p.G73= | Silent (SNP) | VAF 93/222 reads (42%) | catalogued as COSV99564145; called by muse, mutect2, varscan2
- ARHGAP30 | c.3228T>C p.P1076= (on ENST00000368013 / NM_001025598.2; = p.P865= on NM_181720.3) | Silent (SNP) | VAF 75/512 reads (15%) | called by muse, mutect2, varscan2
- ATF6B | c.1731G>A p.S577= | Silent (SNP) | VAF 141/383 reads (37%) | catalogued as rs6926448; called by muse, mutect2, varscan2
- AWAT2 | c.204C>T p.R68= | Silent (SNP) | VAF 120/336 reads (36%) | called by muse, mutect2, varscan2
- BICD2 | c.2145T>C p.Y715= | Silent (SNP) | VAF 31/324 reads (10%) | catalogued as rs1042399429; ClinVar: likely benign; called by muse, mutect2
- C1QTNF2 | c.984C>T p.N328= (on ENST00000393975; = p.N283= on NM_031908.6 and 1 other RefSeq transcript) | Silent (SNP) | VAF 79/174 reads (45%) | catalogued as rs773134321, COSV101220864; called by muse, mutect2, varscan2
- C8orf48 | c.678A>G p.L226= | Silent (SNP) | VAF 107/259 reads (41%) | called by muse, mutect2, varscan2
- CAPN15 | c.2436C>T p.P812= | Silent (SNP) | VAF 254/581 reads (44%) | catalogued as rs553459831; called by muse, mutect2, varscan2
- CBLL2 | c.264C>T p.V88= | Silent (SNP) | VAF 165/395 reads (42%) | catalogued as rs1160520299, COSV60369924; called by muse, mutect2, varscan2
- CDIP1 | c.624C>T p.C208= | Silent (SNP) | VAF 111/239 reads (46%) | called by muse, mutect2, varscan2
- CHD3 | c.4581C>T p.R1527= | Silent (SNP) | VAF 189/441 reads (43%) | catalogued as rs369890808; called by muse, mutect2, varscan2
- CHRM1 | c.1098C>T p.T366= | Silent (SNP) | VAF 32/421 reads (8%) | called by muse, mutect2
- CLASRP | c.1638G>A p.A546= | Silent (SNP) | VAF 165/410 reads (40%) | catalogued as rs377491505; called by muse, mutect2, varscan2
- CPAMD8 | c.2835C>T p.C945= (on ENST00000651564; = p.C898= on NM_015692.5) | Silent (SNP) | VAF 14/298 reads (5%) | catalogued as COSV71596118; called by muse, mutect2
- CPPED1 | c.807C>T p.C269= | Silent (SNP) | VAF 136/362 reads (38%) | called by muse, mutect2, varscan2
- CRTC1 | c.1623C>T p.H541= | Silent (SNP) | VAF 150/393 reads (38%) | catalogued as rs985853392; called by muse, varscan2
- DDX20 | c.406T>C p.L136= | Silent (SNP) | VAF 76/185 reads (41%) | called by muse, varscan2
- DEGS1 | c.255T>C p.T85= | Silent (SNP) | VAF 108/502 reads (22%) | called by muse, varscan2
- DENND11 | c.1272C>G p.G424= | Silent (SNP) | VAF 195/554 reads (35%) | catalogued as rs372660707; called by muse, mutect2, varscan2
- DES | c.999C>T p.C333= | Silent (SNP) | VAF 78/213 reads (37%) | catalogued as rs1157722667, COSV64660988, COSV64661225; ClinVar: uncertain significance / likely benign; called by muse, mutect2
- DHX9 | c.1581G>A p.L527= | Silent (SNP) | VAF 79/394 reads (20%) | catalogued as rs540519177; called by muse, mutect2, varscan2
- DKKL1 | c.633C>T p.D211= | Silent (SNP) | VAF 166/372 reads (45%) | catalogued as rs763530004; called by muse, varscan2
- DNAH17 | c.2061T>C p.Y687= | Silent (SNP) | VAF 111/292 reads (38%) | catalogued as rs771832526; called by muse, mutect2, varscan2
- DNAH9 | c.9834G>T p.V3278= | Silent (SNP) | VAF 17/331 reads (5%) | catalogued as COSV52344181; called by muse, mutect2
- ETS2 | c.1065C>T p.A355= | Silent (SNP) | VAF 78/186 reads (42%) | catalogued as rs745562769; called by muse, varscan2
- FAM174A | c.300C>T p.A100= | Silent (SNP) | VAF 18/478 reads (4%) | catalogued as COSV100444197; called by muse, mutect2
- FAXDC2 | c.537G>A p.T179= | Silent (SNP) | VAF 89/260 reads (34%) | catalogued as rs759823090; called by muse, mutect2, varscan2
- FBXO21 | c.955C>T p.L319= | Silent (SNP) | VAF 138/312 reads (44%) | called by muse, varscan2
- FGFR1OP2 | c.159T>C p.L53= | Silent (SNP) | VAF 47/158 reads (30%) | called by muse, mutect2, varscan2
- FMN1 | c.3681C>T p.Y1227= (on ENST00000616417 / NM_001277313.2; = p.Y1004= on NM_001103184.4) | Silent (SNP) | VAF 101/239 reads (42%) | catalogued as rs201891354, COSV57926433; ClinVar: likely benign; called by muse, mutect2, varscan2
- FMNL1 | c.3063G>A p.P1021= | Silent (SNP) | VAF 102/245 reads (42%) | catalogued as rs764125862, COSV100057021; called by muse, mutect2, varscan2
- FXYD7 | c.57C>T p.Y19= | Silent (SNP) | VAF 104/238 reads (44%) | called by muse, mutect2, varscan2
- FZD2 | c.549G>A p.P183= | Silent (SNP) | VAF 94/251 reads (37%) | called by muse, mutect2, varscan2
- GABRA4 | c.39C>T p.S13= | Silent (SNP) | VAF 30/253 reads (12%) | catalogued as COSV51931572; called by muse, mutect2, varscan2
- GALNT11 | c.780C>T p.A260= | Silent (SNP) | VAF 18/290 reads (6%) | catalogued as rs376062613; called by muse, mutect2
- GGPS1 | c.615T>C p.C205= | Silent (SNP) | VAF 160/642 reads (25%) | catalogued as rs772423462; called by muse, mutect2, varscan2
- GJA4 | c.489T>C p.S163= | Silent (SNP) | VAF 159/362 reads (44%) | catalogued as rs1262810679; called by muse, varscan2
- GNPTAB | c.2397T>C p.G799= | Silent (SNP) | VAF 144/359 reads (40%) | catalogued as COSV68449794; called by muse, mutect2, varscan2
- GPIHBP1 | c.42C>T p.F14= | Silent (SNP) | VAF 104/296 reads (35%) | catalogued as rs749010241; called by muse, mutect2, varscan2
- GRIN2D | c.2394C>T p.R798= | Silent (SNP) | VAF 160/378 reads (42%) | called by muse, varscan2
- HERC1 | c.10509C>T p.G3503= | Silent (SNP) | VAF 15/243 reads (6%) | catalogued as rs1008671202, COSV71250167; called by muse, mutect2
- HKDC1 | c.96C>T p.S32= | Silent (SNP) | VAF 106/291 reads (36%) | catalogued as rs768438980; called by muse, mutect2, varscan2
- HSPA2 | c.525C>T p.N175= | Silent (SNP) | VAF 45/310 reads (15%) | called by muse, mutect2, varscan2
- HTATSF1 | c.2256C>T p.D752= | Silent (SNP) | VAF 84/238 reads (35%) | catalogued as rs34882252; called by muse, mutect2, varscan2
- INTS6L | c.1431A>G p.T477= | Silent (SNP) | VAF 112/328 reads (34%) | called by muse, mutect2, varscan2
- ITGA7 | c.1071G>A p.G357= (on ENST00000555728; = p.G313= on NM_002206.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 134/328 reads (41%) | called by muse, varscan2
- JARID2 | c.1635C>T p.G545= | Silent (SNP) | VAF 193/476 reads (41%) | catalogued as rs777889447, COSV59190266; called by muse, varscan2
- KCNA5 | c.45C>A p.T15= | Silent (SNP) | VAF 44/420 reads (10%) | catalogued as rs1270826831, COSV52908494; called by muse, mutect2, varscan2
- KCP | c.3429C>T p.R1143= (on ENST00000620378; = p.R1267= on NM_001366122.1) | Silent (SNP) | VAF 134/322 reads (42%) | called by muse, varscan2
- KDM7A | c.2626C>T p.L876= | Silent (SNP) | VAF 150/397 reads (38%) | called by muse, mutect2, varscan2
- KMT2D | c.13287G>A p.Q4429= | Silent (SNP) | VAF 16/475 reads (3%) | called by muse, mutect2
- LIPE | c.429A>G p.P143= | Silent (SNP) | VAF 16/416 reads (4%) | catalogued as rs1233885209; called by muse, mutect2
- LMTK3 | c.3198C>T p.N1066= | Silent (SNP) | VAF 177/463 reads (38%) | catalogued as rs766916333; called by muse, mutect2, varscan2
- LNX2 | c.597A>G p.T199= | Silent (SNP) | VAF 164/394 reads (42%) | catalogued as rs768422499; called by muse, mutect2
- MATN3 | c.180G>A p.A60= | Silent (SNP) | VAF 134/356 reads (38%) | called by muse, mutect2, varscan2
- MCCC2 | c.1119C>T p.N373= | Silent (SNP) | VAF 95/245 reads (39%) | catalogued as rs766440020; called by muse, mutect2, varscan2
- MCTP1 | c.2805G>A p.P935= | Silent (SNP) | VAF 23/220 reads (10%) | catalogued as rs373763484; called by muse, mutect2, varscan2
- MDH2 | c.333C>T p.D111= | Silent (SNP) | VAF 104/262 reads (40%) | catalogued as rs529395182; called by muse, varscan2
- MFHAS1 | c.903C>T p.L301= | Silent (SNP) | VAF 116/318 reads (36%) | called by muse, mutect2, varscan2
- MGA | c.3501A>G p.V1167= | Silent (SNP) | VAF 125/291 reads (43%) | called by muse, mutect2, varscan2
- MMP15 | c.921C>T p.D307= | Silent (SNP) | VAF 136/320 reads (43%) | catalogued as rs771141615; called by muse, mutect2, varscan2
- MORC4 | c.1737C>T p.L579= | Silent (SNP) | VAF 147/356 reads (41%) | called by muse, mutect2, varscan2
- MST1R | c.3912G>A p.R1304= | Silent (SNP) | VAF 14/356 reads (4%) | catalogued as rs1332518765; called by muse, mutect2
- MTMR3 | c.3558C>T p.D1186= | Silent (SNP) | VAF 39/337 reads (12%) | called by muse, mutect2, varscan2
- MYH7B | c.438C>A p.R146= | Silent (SNP) | VAF 146/354 reads (41%) | called by muse, mutect2, varscan2
- MYO18A | c.3291C>T p.R1097= | Silent (SNP) | VAF 141/339 reads (42%) | catalogued as rs997767094, COSV100572853; called by muse, mutect2, varscan2
- MYO1A | c.1203T>C p.N401= | Silent (SNP) | VAF 22/268 reads (8%) | called by muse, mutect2
- NGEF | c.1857C>T p.C619= | Silent (SNP) | VAF 103/289 reads (36%) | catalogued as rs771518876, COSV99888504; called by muse, mutect2, varscan2
- NINL | c.2001C>T p.R667= | Silent (SNP) | VAF 174/469 reads (37%) | catalogued as rs751930908; called by muse, mutect2, varscan2
- NTN3 | c.303G>A p.A101= | Silent (SNP) | VAF 54/476 reads (11%) | catalogued as rs757893479; called by muse, varscan2
- OFD1 | c.2349C>A p.S783= | Silent (SNP) | VAF 155/353 reads (44%) | catalogued as CD060636, COSV100407019; called by muse, mutect2, varscan2
- OR2G3 | c.612T>C p.V204= | Silent (SNP) | VAF 130/576 reads (23%) | called by muse, mutect2, varscan2
- OR51D1 | c.600G>A p.L200= | Silent (SNP) | VAF 136/339 reads (40%) | catalogued as COSV62914780; called by muse, mutect2, varscan2
- OR56A1 | c.402G>A p.R134= | Silent (SNP) | VAF 102/243 reads (42%) | catalogued as COSV57362244; called by muse, varscan2
- PAK1IP1 | c.447G>A p.T149= | Silent (SNP) | VAF 71/213 reads (33%) | catalogued as rs760790904; called by muse, mutect2, varscan2
- PCDH8 | c.963G>A p.E321= | Silent (SNP) | VAF 238/528 reads (45%) | called by muse, mutect2, varscan2
- PDZD4 | c.1635C>T p.R545= | Silent (SNP) | VAF 48/682 reads (7%) | catalogued as rs1361920534; called by muse, mutect2
- PIEZO2 | c.7074A>G p.T2358= | Silent (SNP) | VAF 20/408 reads (5%) | called by muse, mutect2
- PLA2G12B | c.18C>A p.G6= | Silent (SNP) | VAF 27/262 reads (10%) | called by muse, mutect2, varscan2
- PLK2 | c.906A>G p.S302= | Silent (SNP) | VAF 111/358 reads (31%) | catalogued as rs765295814; called by muse, mutect2
- PROKR1 | c.1026C>T p.F342= | Silent (SNP) | VAF 108/276 reads (39%) | catalogued as COSV100375400; called by muse, varscan2
- PRSS35 | c.303A>G p.Q101= | Silent (SNP) | VAF 87/208 reads (42%) | catalogued as COSV63800053; called by muse, mutect2, varscan2
- PTPN23 | c.4197G>A p.T1399= | Silent (SNP) | VAF 30/269 reads (11%) | catalogued as rs746108051; called by muse, mutect2, varscan2
- RFX1 | c.684G>A p.V228= | Silent (SNP) | VAF 190/401 reads (47%) | called by muse, mutect2, varscan2
- RNF213 | c.6321G>A p.P2107= | Silent (SNP) | VAF 114/249 reads (46%) | catalogued as rs777754815; called by muse, mutect2, varscan2
- RRNAD1 | c.108C>A p.I36= | Silent (SNP) | VAF 87/382 reads (23%) | called by muse, varscan2
- SBK1 | c.1203C>T p.G401= | Silent (SNP) | VAF 52/470 reads (11%) | catalogued as rs1186665381; called by muse, varscan2
- SBNO2 | c.4029G>A p.A1343= | Silent (SNP) | VAF 166/376 reads (44%) | catalogued as rs781014228, COSV62323195; called by muse, mutect2, varscan2
- SEC23B | c.702T>C p.P234= | Silent (SNP) | VAF 20/288 reads (7%) | catalogued as rs1229685001; called by muse, mutect2
- SETD1B | c.5706C>T p.R1902= | Silent (SNP) | VAF 33/349 reads (9%) | called by muse, mutect2, varscan2
- SLC35A4 | c.639G>A p.Q213= | Silent (SNP) | VAF 128/366 reads (35%) | called by muse, mutect2, varscan2
- SLC9A3R1 | c.175C>T p.L59= | Silent (SNP) | VAF 158/416 reads (38%) | called by muse, mutect2, varscan2
- SLF1 | c.1605G>A p.T535= | Silent (SNP) | VAF 94/244 reads (39%) | catalogued as rs774988916; called by muse, varscan2
- SMARCD2 | c.1290G>A p.Q430= | Silent (SNP) | VAF 25/348 reads (7%) | called by muse, mutect2
- SRP72 | c.1800A>G p.K600= | Silent (SNP) | VAF 123/294 reads (42%) | catalogued as rs766240259; called by muse, varscan2
- STAB1 | c.1068C>T p.Y356= | Silent (SNP) | VAF 177/404 reads (44%) | catalogued as rs138924200; called by muse, mutect2, varscan2
- SUSD1 | c.1956C>T p.Y652= | Silent (SNP) | VAF 40/416 reads (10%) | catalogued as rs773908311, COSV62585345; called by muse, mutect2
- TFEC | c.822G>A p.E274= | Silent (SNP) | VAF 97/249 reads (39%) | called by muse, mutect2, varscan2
- TLCD1 | c.153C>A p.S51= | Silent (SNP) | VAF 40/438 reads (9%) | called by muse, mutect2
- TMEM125 | c.238C>T p.L80= | Silent (SNP) | VAF 148/356 reads (42%) | called by muse, varscan2
- TNRC18 | c.5716C>T p.L1906= | Silent (SNP) | VAF 12/158 reads (8%) | catalogued as rs1444110817; called by muse, mutect2
- TNRC6B | c.5448C>T p.S1816= (on ENST00000454349 / NM_001162501.2; = p.S1706= on NM_015088.3) | Silent (SNP) | VAF 95/237 reads (40%) | catalogued as rs752749800; called by muse, mutect2, varscan2
- TRBV20-1 | c.105C>T p.I35= | Silent (SNP) | VAF 171/378 reads (45%) | catalogued as rs780750911; called by muse, mutect2, varscan2
- TRIT1 | c.357G>A p.V119= | Silent (SNP) | VAF 64/203 reads (32%) | called by muse, mutect2, varscan2
- TSPYL1 | c.258T>C p.V86= | Silent (SNP) | VAF 45/376 reads (12%) | called by muse, mutect2, varscan2
- UBE2L5 | c.81T>C p.V27= | Silent (SNP) | VAF 155/423 reads (37%) | called by muse, mutect2, varscan2
- UBR4 | c.15264C>T p.S5088= | Silent (SNP) | VAF 99/246 reads (40%) | catalogued as rs763127905, COSV64399181; ClinVar: likely benign; called by muse, mutect2, varscan2
- VASH1 | c.243G>T p.V81= | Silent (SNP) | VAF 27/442 reads (6%) | called by muse, mutect2
- WDFY4 | c.2764C>T p.L922= | Silent (SNP) | VAF 84/198 reads (42%) | called by muse, mutect2, varscan2
- ZFYVE26 | c.1491C>A p.L497= | Silent (SNP) | VAF 113/255 reads (44%) | catalogued as COSV100720327; called by muse, mutect2, varscan2
- ZMAT4 | c.249A>G p.S83= | Silent (SNP) | VAF 120/336 reads (36%) | called by muse, mutect2, varscan2
- ZMYM2 | c.603A>G p.Q201= | Silent (SNP) | VAF 151/330 reads (46%) | catalogued as rs375228563; called by muse, mutect2, varscan2
- ZMYND8 | c.2763T>C p.D921= (on ENST00000311275 / NM_001363741.2; = p.D895= on NM_012408.6 and 1 other RefSeq transcript) | Silent (SNP) | VAF 89/241 reads (37%) | called by muse, mutect2, varscan2
- ZNF189 | c.1569G>A p.Q523= | Silent (SNP) | VAF 122/330 reads (37%) | called by muse, mutect2, varscan2
- ZNF207 | c.411T>C p.G137= | Silent (SNP) | VAF 27/401 reads (7%) | catalogued as rs1264040558; called by muse, mutect2
- ZNF33B | c.504C>T p.D168= | Silent (SNP) | VAF 84/205 reads (41%) | catalogued as rs370800363; called by muse, mutect2, varscan2
- ACBD4 | chr17:45143501 T>C | 3'Flank (SNP) | VAF 38/434 reads (9%) | called by muse, mutect2
- CTBP2 | c.58+12337C>T | Intron (SNP) | VAF 176/412 reads (43%) | catalogued as rs923247180, COSV58345539; called by muse, mutect2, varscan2
- FAM9B | c.-79C>T | 5'UTR (SNP) | VAF 155/364 reads (43%) | catalogued as rs267606528; called by muse, varscan2
- KCNQ1 | c.1393+21727G>A | Intron (SNP) | VAF 89/250 reads (36%) | called by muse, mutect2, varscan2
- KDM2B | c.1048-3449T>A | Intron (SNP) | VAF 57/141 reads (40%) | called by mutect2, varscan2
- MUCL3 | c.947-663A>T | Intron (SNP) | VAF 187/529 reads (35%) | called by muse, mutect2, varscan2
- NTRK3 | c.2133+12636G>A | Intron (SNP) | VAF 88/220 reads (40%) | catalogued as rs757853638; called by muse, mutect2, varscan2
- OBSCN | c.11660-2050A>G | Intron (SNP) | VAF 24/414 reads (6%) | catalogued as rs767384357; called by muse, mutect2
- PLEKHB2 | c.533-2212C>T | Intron (SNP) | VAF 57/175 reads (33%) | catalogued as rs1017078070; called by muse, mutect2, varscan2
- REV3L | c.-286G>A | 5'UTR (SNP) | VAF 40/297 reads (13%) | called by muse, mutect2, varscan2
- SCNN1A | c.-105C>T | 5'UTR (SNP) | VAF 138/337 reads (41%) | catalogued as rs1003784925; called by muse, varscan2
- SH2B2 | chr7:102283058 A>G | 5'Flank (SNP) | VAF 148/347 reads (43%) | called by muse, mutect2, varscan2
- SH3KBP1 | c.-265A>G | 5'UTR (SNP) | VAF 59/149 reads (40%) | called by muse, mutect2, varscan2
- SLC39A1 | c.*831del | 3'UTR (DEL) | VAF 100/584 reads (17%) | called by pindel, varscan2
- SNX20 | chr16:50669142 ins C | 3'Flank (INS) | VAF 104/254 reads (41%) | called by mutect2, pindel, varscan2
- SPATS2 | c.25+1439A>G | Intron (SNP) | VAF 21/211 reads (10%) | called by muse, mutect2, varscan2
- SYNPO | chr5:150656960 T>G | 3'Flank (SNP) | VAF 141/398 reads (35%) | called by muse, mutect2, varscan2
- UNC13B | c.761+5105C>T | Intron (SNP) | VAF 91/220 reads (41%) | called by muse, varscan2
- UNC13B | c.1168-14652A>G | Intron (SNP) | VAF 146/345 reads (42%) | called by muse, mutect2, varscan2
- WDR49 | c.-65-17001A>G | Intron (SNP) | VAF 9/181 reads (5%) | called by muse, mutect2
